Somatic mutation profile of tumor specimen TCGA-AX-A3G7-01A (aliquot TCGA-AX-A3G7-01A-12D-A20S-09) from TCGA case TCGA-AX-A3G7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,187 days).
Specimen TCGA-AX-A3G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fa73b78-528d-4b92-9ad5-65c098276740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3G7-10A (Blood Derived Normal), aliquot TCGA-AX-A3G7-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc39885b-66e4-428f-86c5-08a3ac29850d

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 16, Silent 8, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 16/46 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 30/43 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALDH18A1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1320690165, COSV100973180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.4195C>T p.R1399C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374596109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CANX | c.373C>G p.R125G | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV99910578; called by muse, mutect2, varscan2
- CCNB3 | c.3242A>T p.K1081M | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99329464; called by muse, mutect2, varscan2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- DENR | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99757399; called by muse, mutect2, varscan2
- FTSJ1 | c.469-1G>T p.X157_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99191437; called by mutect2, varscan2
- GPRASP1 | c.4103C>T p.A1368V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV100851041; called by muse, mutect2, varscan2
- IQSEC3 | c.2440C>T p.R814* (on ENST00000538872 / NM_001170738.2; = p.R511* on NM_015232.1) | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV58284083; called by muse, mutect2, varscan2
- NELL2 | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV100418344, COSV100420210, COSV61576556; called by muse, mutect2, varscan2
- PTEN | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64301083; called by muse, mutect2, varscan2
- RIMS1 | c.1552C>G p.R518G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99328761; called by muse, mutect2, varscan2
- SPRY3 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.3); catalogued as rs771224871, COSV57142834; called by muse, mutect2
- TUT1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs773625224, COSV99545478; called by muse, mutect2, varscan2
- ZNF275 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100936380, COSV64704660; called by muse, mutect2, varscan2
- ZNF282 | c.1129T>C p.W377R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.854); catalogued as COSV100021789; called by muse, mutect2, varscan2
- IL1RL1 | c.130del p.Y44Tfs*29 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- SRPK2 | c.1405del p.S469Lfs*45 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | called by mutect2, pindel, varscan2
- CD19 | c.648T>C p.H216= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs773089937, COSV100218209; called by muse, mutect2, varscan2
- CEACAM21 | c.675C>T p.S225= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1461691598, COSV99494683; called by muse, mutect2, varscan2
- CEP95 | c.864C>T p.C288= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV101616326; called by muse, mutect2, varscan2
- DSPP | c.618C>T p.N206= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs754990176, COSV56808335; called by muse, mutect2, varscan2
- FAM50A | c.393C>T p.G131= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1474013036, COSV50133034; called by muse, mutect2, varscan2
- OR2T3 | c.402T>G p.P134= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV100613311; called by muse, mutect2, varscan2
- UMPS | c.1356C>T p.G452= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs1452139075, COSV99229200; called by muse, mutect2, varscan2
- ZNF230 | c.588T>A p.S196= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101432062; called by muse, mutect2, varscan2
